Somatic mutation profile of tumor specimen MP2PRT-PAUGEZ-TMP1-A (aliquot MP2PRT-PAUGEZ-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUGEZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,809 days).
Specimen MP2PRT-PAUGEZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19f6552a-0e3e-43ca-b70f-1af35d2c79bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGEZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGEZ-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1982d2f6-a292-416c-a3c6-e22923f6f5eb

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, In Frame Ins 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 156/358 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62393312; called by muse, varscan2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- CYP11B2 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 22/789 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs970961565; called by muse, mutect2
- TBC1D2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 154/722 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755332434, COSV59784219; called by muse, varscan2
- TRIM24 | c.2440C>T p.H814Y (on ENST00000343526 / NM_015905.3; = p.H780Y on NM_003852.4) | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs940936849; called by muse, mutect2, varscan2
- POLR1A | c.980_981insAGA p.N327delinsKD | In Frame Ins (INS) | VAF 89/410 reads (22%) | called by mutect2, pindel, varscan2
- SHTN1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- VLDLR | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 110/512 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- JAG2 | c.816C>T p.F272= | Silent (SNP) | VAF 19/491 reads (4%) | catalogued as rs1251796033; called by muse, mutect2
